Gene-level copy-number profile of tumor specimen TARGET-40-PATKSS-01A from TARGET case TARGET-40-PATKSS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Age at diagnosis: 13.4 years (4,889 days).
Specimen TARGET-40-PATKSS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.adab2dc7-984f-5dd2-95a7-7f67b3d8b817.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PATKSS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 404 have no estimate.
https://portal.gdc.cancer.gov/files/494a14aa-11f7-4d69-81f0-e63196e58524

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 15,778; copy number 2: 37,321; copy number 3: 6,121; copy number 4: 216; copy number 5: 73; copy number 6: 169; copy number 7: 35; copy number 8: 70; copy number 9: 8; copy number 11: 99; copy number 14: 5; copy number 16: 101; copy number 17: 194; copy number 18: 11.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:164,119,098–164,234,097, 2 genes: AC008662.1, AC008662.2.
- chr5:164,448,161–164,601,452, 2 genes: LINC02143, AC008446.1.
- chr16:6,380,476–6,748,969, 5 genes: AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P.
- chr22:50,245,183–50,475,035, 9 genes: HDAC10, MAPK12, MAPK11, PLXNB2, DENND6B, CR559946.1, CR559946.2, PPP6R2, SBF1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 719 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–143,934,776, 19 genes, copy number 8–9 (within-gene range 3–9): AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1.
- chr8:150,584–6,407,142, 81 genes, copy number 6–18 (broad region; genes not listed).
- chr8:6,473,845–6,474,288, 1 gene, copy number 6: AC016065.2.
- chr8:24,295,814–24,912,073, 1 gene, copy number 6 (within-gene range 3–6): AC120193.1.
- chr8:24,440,930–26,372,680, 26 genes, copy number 6: ADAM7, AC024958.1, AF106564.1, NEFM, NEFL, MIR6841, AC107373.2, AC107373.1, AC107373.3, AC073581.1, AC041005.1, DOCK5, AC091185.2, MIR6876, GNRH1, AC091185.1, KCTD9, CDCA2, AC009623.1, AC009623.2, AC009623.3, AC090103.1, EBF2, RNA5SP258, AC079097.1, PPP2R2A.
- chr8:35,235,475–41,440,419, 119 genes, copy number 6 (broad region; genes not listed).
- chr17:9,896,320–11,242,062, 34 genes, copy number 6–7: RCVRN, GAS7, RPS27AP1, AC005291.2, MYH13, AC005291.1, AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2, AC005323.1, MYH3, AC002347.1, SCO1, AC002347.2, ADPRM, TMEM220, MAGOH2P, TMEM220-AS1, AC015908.7, AC015908.3, AC015908.1, AC015908.4, AC015908.6, TMEM238L, AC015908.5, PIRT, AC015908.2, RNU6-1065P, RPL15P21, RN7SL601P, AC005548.1.
- chr17:11,288,205–11,290,811, 1 gene, copy number 7: AC005725.1.
- chr17:11,874,727–22,706,703, 437 genes, copy number 5–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,279. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
